Somatic mutation profile of tumor specimen TCGA-86-8075-01A (aliquot TCGA-86-8075-01A-11D-2238-08) from TCGA case TCGA-86-8075, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 66.8 years (24,402 days).
Specimen TCGA-86-8075-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fb8bda1-9ca8-480d-9c64-08114554bf71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-86-8075-10A (Blood Derived Normal), aliquot TCGA-86-8075-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ee9ff69-bbba-4d72-a9f4-e2e4b282799e

The open-access MAF lists 46 somatic variants for this specimen: 37 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 32, Silent 9, Frame Shift Del 2, In Frame Del 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 65/150 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.376-2A>G p.X126_splice | Splice Site (SNP) | VAF 9/21 reads (43%) | hotspot (GDC flag); catalogued as rs786202799, CS114003, COSV52689235, COSV52691326, COSV53121815, COSV53758902; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.2654G>A p.R885H (on ENST00000404938 / NM_001163941.2; = p.R440H on NM_178559.6) | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs111647033; called by muse, mutect2, varscan2
- ANXA4 | c.154C>G p.Q52E | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV67849074; called by muse, mutect2
- ARHGEF40 | c.2347C>T p.R783W | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as rs762564238, COSV53881515; called by mutect2, varscan2
- BRAT1 | c.1645C>G p.L549V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100500683, COSV61395980; called by muse, mutect2, varscan2
- CDYL2 | c.133C>T p.L45F | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV73647731; called by muse, mutect2, varscan2
- CHCHD7 | c.13A>G p.T5A (on ENST00000355315 / NM_001011671.3; = p.T17A on NM_024300.4) | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57612708; called by muse, mutect2, varscan2
- COG2 | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV64187359; called by muse, mutect2, varscan2
- COL6A3 | c.9450C>A p.N3150K | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1327434207, COSV55095115; called by muse, mutect2, varscan2
- DCTN5 | c.314G>A p.G105D | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55615753; called by muse, mutect2, varscan2
- FAM71E1 | c.508G>A p.A170T (on ENST00000600100 / NM_001308429.2; = p.A154T on NM_138411.3) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV58542555; called by muse, mutect2, varscan2
- FLII | c.1148C>G p.A383G | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as COSV58945886; called by muse, mutect2, varscan2
- FRMPD1 | c.275G>A p.G92D | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63383513; called by muse, mutect2, varscan2
- GDF7 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.241); catalogued as COSV55348030; called by muse, mutect2, varscan2
- GNL1 | c.584C>G p.T195S | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV64835345; called by muse, mutect2, varscan2
- HOXB1 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53317787; called by muse, mutect2
- HS3ST5 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs766165768, COSV57135180; called by muse, mutect2, varscan2
- HSD17B12 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs769775264, COSV53501014; called by muse, mutect2, varscan2
- LAMA2 | c.7231G>A p.V2411I | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.616); catalogued as rs199814707; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MATN3 | c.1184C>A p.A395D | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV68100109; called by muse, mutect2
- MYO9A | c.6515C>T p.S2172F | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs151292865; called by muse, mutect2, varscan2
- NGF | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.05); catalogued as rs199511298; called by muse, mutect2, varscan2
- NISCH | c.4394del p.R1465Lfs*99 | Frame Shift Del (DEL) | VAF 49/130 reads (38%) | catalogued as COSV58742775; called by mutect2, pindel, varscan2
- OR4C46 | c.429G>T p.M143I | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV60220059; called by muse, mutect2
- PDE5A | c.2572G>C p.E858Q | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as COSV53349691; called by muse, mutect2, varscan2
- RNASE11 | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs752786357, COSV60087346; called by muse, mutect2
- SEPTIN6 | c.481T>A p.S161T | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59715210; called by muse, mutect2
- TMPRSS13 | c.1523A>G p.Q508R | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70626692; called by muse, mutect2, varscan2
- TYRO3 | c.1174G>A p.V392I | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as rs375597382; called by muse, mutect2, varscan2
- UBE2Z | c.374C>T p.T125I | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.449); catalogued as COSV62876271; called by muse, mutect2
- UBE3A | c.1767G>A p.M589I | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51667426; called by muse, mutect2
- UNC5C | c.1801C>T p.L601F | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as COSV71660710; called by muse, mutect2
- ZNF746 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs766494668, COSV61406835; called by muse, mutect2, varscan2
- BRWD1 | c.4501dup p.T1501Nfs*4 | Frame Shift Ins (INS) | VAF 6/39 reads (15%) | called by mutect2, pindel, varscan2
- DEPDC7 | c.1217_1234del p.D406_L412delinsV (on ENST00000241051 / NM_001077242.2; = p.D397_L403delinsV on NM_139160.2) | In Frame Del (DEL) | VAF 17/58 reads (29%) | called by mutect2, pindel, varscan2
- SUMO1 | c.242del p.G81Efs*7 | Frame Shift Del (DEL) | VAF 30/258 reads (12%) | called by mutect2, pindel
- ASIC4 | c.618C>T p.N206= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as rs148269786, COSV61733482; called by muse, mutect2, varscan2
- CYFIP1 | c.1905G>A p.R635= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- DENND2B | c.1269C>T p.P423= | Silent (SNP) | VAF 18/222 reads (8%) | catalogued as COSV58205143; called by muse, mutect2
- IFNA16 | c.552A>C p.G184= | Silent (SNP) | VAF 27/135 reads (20%) | catalogued as COSV66510314; called by muse, mutect2, varscan2
- NT5M | c.322C>T p.L108= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as rs1380245794, COSV66519165; called by muse, mutect2, varscan2
- SLC16A14 | c.1458C>T p.L486= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV54619342; called by muse, mutect2, varscan2
- SLC2A10 | c.1344C>T p.F448= | Silent (SNP) | VAF 42/89 reads (47%) | catalogued as rs553831434, COSV63715138; called by muse, mutect2, varscan2
- SORCS1 | c.2406A>T p.I802= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV53877867; called by muse, mutect2, varscan2
- VPS13B | c.5949G>A p.V1983= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV62147027; called by muse, mutect2
